MMRF case MMRF_1935 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2de061bb-7a1a-4041-a2a3-de6e1cf3a3e4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.6 years (17,034 days); ISS stage: I; Days to last known disease status: 1,062 days (2.9 years); Days to last follow up: 1,062 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 611 days (1.7 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 285 days; Days to treatment end: 285 days.
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 804 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 574 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.58 mmol/L; Albumin 48 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.053 mg/dL.
- Day 91 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 9.4 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.45 mmol/L.
- Day 201 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 4.24 mmol/L.
- Day 308 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.542 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.22 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.83 mmol/L.
- Day 404 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 4.31 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 503: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 600: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.835 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 686 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.4 mmol/L.
- Day 749 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 847: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 6.95 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 5.6 g/dL; Glucose 5.23 mmol/L.
- Day 910: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.57 mmol/L.
- Day 982: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 1,062: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -8: Weight: 102 kg; Height: 187 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1935_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1935_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
